Somatic mutation profile of tumor specimen 0DR1ZB from CCDI case PBCFYA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 1.5 years (556 days).
Specimen 0DR1ZB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75d30cb3-d20e-4b70-8902-8b3794dba316.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/881994b2-daa5-41a4-b0e3-3b5d61182484

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 95/881 reads (11%) | catalogued as rs63751127, CM045066, COSV52279460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC158 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 115/1010 reads (11%) | catalogued as rs758087871; called by muse, mutect2, varscan2
- DERA | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 306/1252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921899789; called by muse, mutect2, varscan2
- FIZ1 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1468387034; called by muse, mutect2
- NUP107 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 109/1440 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs768210223, COSV57498109; called by muse, mutect2
- OMP | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs146523768; called by muse, mutect2, varscan2
- OR52D1 | c.810C>A p.H270Q | Missense Mutation (SNP) | VAF 59/1329 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV100495139; called by muse, mutect2
- UPK1A | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs138336912; called by muse, mutect2
- ABCA9 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 161/1146 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- EEF1A1 | c.204A>C p.E68D | Missense Mutation (SNP) | VAF 116/1243 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MICA | c.949_961del p.A317Ifs*65 | Frame Shift Del (DEL) | VAF 7/75 reads (9%) | called by mutect2*, pindel
- LCOR | c.4395G>C p.G1465= | Silent (SNP) | VAF 21/762 reads (3%) | called by muse, mutect2
- PRKCA | c.1482G>A p.T494= | Silent (SNP) | VAF 70/952 reads (7%) | catalogued as rs753622928, COSV52585059; called by muse, mutect2
